Somatic mutation profile of tumor specimen C3L-01154-02 (aliquot CPT0218830007) from CPTAC case C3L-01154, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 52.0 years (18,992 days).
Specimen C3L-01154-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86f6f035-353f-4e62-af13-149c3966a71f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01154-31 (Blood Derived Normal), aliquot CPT0220370002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e010dd0-ee7b-468f-8e6a-417987000876

The open-access MAF lists 54 somatic variants for this specimen: 38 protein-altering or splice-affecting, 11 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 11, Intron 4, Nonsense Mutation 3, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC134980.2 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 79/114 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs200194923, COSV100171580; called by muse, mutect2, varscan2
- BCOR | c.1222G>A p.G408R | Missense Mutation (SNP) | VAF 267/640 reads (42%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.885); catalogued as rs1406831429, COSV60714195; called by muse, mutect2, varscan2
- BPIFB1 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 102/258 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.186); catalogued as rs551400282, COSV53608711; called by muse, mutect2, varscan2
- CENPS | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 65/164 reads (40%) | catalogued as rs201711835; called by muse, mutect2, varscan2
- CHD5 | c.5128G>A p.G1710R | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769117837; called by muse, mutect2, varscan2
- DCST2 | c.1255G>A p.V419M | Missense Mutation (SNP) | VAF 122/317 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs200037746; called by muse, mutect2, varscan2
- DOCK6 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 125/323 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1421978495, COSV52949184; called by muse, mutect2, varscan2
- DSG4 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs769990795, COSV57388631; called by muse, mutect2
- EXOC2 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 121/280 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.103); catalogued as rs138470165; called by muse, mutect2, varscan2
- MAP3K1 | c.971C>G p.P324R | Missense Mutation (SNP) | VAF 21/511 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68123876; called by muse, mutect2
- MYOM3 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 118/283 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.055); catalogued as rs754203512; called by muse, mutect2, varscan2
- NDST3 | c.2257G>A p.E753K | Missense Mutation (SNP) | VAF 76/169 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs775212321, COSV56628137, COSV56632105; called by muse, mutect2
- OR5R1 | c.188T>G p.L63R | Missense Mutation (SNP) | VAF 69/156 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100393597; called by muse, mutect2, varscan2
- PCDH11X | c.3151C>T p.R1051W | Missense Mutation (SNP) | VAF 179/429 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs765523053; called by muse, mutect2, varscan2
- PGK2 | c.818C>A p.A273E | Missense Mutation (SNP) | VAF 83/246 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100505500; called by muse, mutect2, varscan2
- PIK3C2G | c.1894G>A p.G632R (on ENST00000676171; = p.G591R on NM_004570.5) | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as rs537382833, COSV56815166; called by muse, mutect2, varscan2
- PLCB1 | c.2354C>T p.T785M | Missense Mutation (SNP) | VAF 92/220 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs202199288; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- PSG1 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as rs530270765; called by muse, mutect2, varscan2
- SIGLEC9 | c.71C>T p.T24M | Missense Mutation (SNP) | VAF 97/225 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs753561495, COSV51582423, COSV51585007; called by muse, mutect2, varscan2
- SOHLH2 | c.158C>T p.T53M | Missense Mutation (SNP) | VAF 233/273 reads (85%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs142901524; called by muse, mutect2, varscan2
- TMTC2 | c.1741C>T p.R581* | Nonsense Mutation (SNP) | VAF 153/361 reads (42%) | catalogued as rs747399728; called by muse, mutect2, varscan2
- TRAPPC9 | c.2286G>T p.L762F | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV101226930; called by muse, mutect2, varscan2
- TTC16 | c.1579C>T p.R527W | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs570570464, COSV100263304; called by muse, mutect2, varscan2
- TTN | c.8630T>C p.L2877P (on ENST00000591111; = p.L2831P on NM_003319.4) | Missense Mutation (SNP) | VAF 165/413 reads (40%) | PolyPhen probably damaging (0.977); catalogued as COSV60265104; called by muse, mutect2, varscan2
- DNAJC16 | c.700G>A p.V234I | Missense Mutation (SNP) | VAF 57/225 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- FAM200B | c.1556T>C p.F519S | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HK2 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 159/426 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- HS3ST3A1 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 85/411 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HTR1E | c.156G>T p.K52N | Missense Mutation (SNP) | VAF 46/64 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LONRF3 | c.410C>G p.A137G | Missense Mutation (SNP) | VAF 217/514 reads (42%) | SIFT tolerated (0.78); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRC41 | c.2365C>T p.R789W | Missense Mutation (SNP) | VAF 110/272 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- LRRIQ1 | c.1493A>T p.K498M | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MGAT5B | c.1157G>C p.R386P | Missense Mutation (SNP) | VAF 81/223 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PIK3R1 | c.1116_1118+20del p.X372_splice (on ENST00000521381 / NM_181523.3; = p.X102_splice on NM_181504.4) | Splice Site (DEL) | VAF 27/64 reads (42%) | called by mutect2, pindel, varscan2
- POMT2 | c.2143T>A p.Y715N | Missense Mutation (SNP) | VAF 192/452 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- SLC14A2 | c.259A>G p.R87G | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- TESPA1 | c.514C>T p.Q172* (on ENST00000316577 / NM_001098815.3; = p.Q34* on NM_014796.2 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 134/284 reads (47%) | called by muse, mutect2, varscan2
- ZBTB7C | c.1730C>T p.A577V | Missense Mutation (SNP) | VAF 24/735 reads (3%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.51); called by muse, mutect2
- AJAP1 | c.144G>A p.P48= | Silent (SNP) | VAF 139/325 reads (43%) | catalogued as rs776421160, COSV65454636; called by muse, mutect2, varscan2
- BCORL1 | c.4605G>A p.K1535= | Silent (SNP) | VAF 112/247 reads (45%) | catalogued as COSV99501394; called by muse, mutect2, varscan2
- C16orf54 | c.33C>T p.R11= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs766863718; called by muse, varscan2
- EGFLAM | c.510C>T p.S170= | Silent (SNP) | VAF 134/325 reads (41%) | catalogued as rs571639364, COSV59305186; called by muse, mutect2, varscan2
- ENTPD6 | c.1113G>A p.T371= | Silent (SNP) | VAF 93/245 reads (38%) | catalogued as rs150868438; called by muse, mutect2, varscan2
- MED12 | c.3540C>T p.F1180= | Silent (SNP) | VAF 283/658 reads (43%) | called by muse, mutect2, varscan2
- PKMYT1 | c.1102C>T p.L368= | Silent (SNP) | VAF 281/701 reads (40%) | called by muse, mutect2, varscan2
- SCN11A | c.3471G>A p.A1157= | Silent (SNP) | VAF 56/236 reads (24%) | catalogued as rs771153034, COSV100181135; ClinVar: likely benign; called by muse, mutect2, varscan2
- TEX13B | c.42C>T p.H14= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs376883010, COSV57202886; called by muse, mutect2, varscan2
- TRIM9 | c.1371C>T p.S457= | Silent (SNP) | VAF 134/331 reads (40%) | catalogued as rs544784389, COSV53615935; called by muse, mutect2, varscan2
- UTP20 | c.1020G>A p.T340= | Silent (SNP) | VAF 40/72 reads (56%) | catalogued as rs774061468, COSV55381340; called by muse, mutect2, varscan2
- EPS8L2 | c.-15G>A | 5'UTR (SNP) | VAF 181/383 reads (47%) | catalogued as rs199799190; called by muse, mutect2, varscan2
- FKBP6 | c.57+26G>A | Intron (SNP) | VAF 99/506 reads (20%) | catalogued as rs1253125719; called by muse, mutect2, varscan2
- KIR3DX1 | n.1182+16C>T | Intron (SNP) | VAF 196/443 reads (44%) | catalogued as rs75027555; called by muse, mutect2, varscan2
- SLC7A9 | c.750-19G>A | Intron (SNP) | VAF 222/481 reads (46%) | catalogued as rs373295164; called by muse, mutect2, varscan2
- SMARCA4 | c.3546+65C>T | Intron (SNP) | VAF 164/371 reads (44%) | catalogued as rs780821981; called by muse, mutect2, varscan2
